Gene-level copy-number profile of tumor specimen C3N-03928-03 from CPTAC case C3N-03928, project CPTAC-3 (Other and unspecified parts of tongue — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tongue, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 60.5 years (22,113 days).
Specimen C3N-03928-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Tongue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 44b9ac35-0412-4a64-8ba2-b17461536f99.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03928-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,220 have no estimate.
https://portal.gdc.cancer.gov/files/9b05a31f-88f8-462b-8cf9-4047d89c509d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 28; copy number 2: 58,331; copy number 3: 44.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 27. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
